Somatic mutation profile of tumor specimen TCGA-CZ-5463-01A (aliquot TCGA-CZ-5463-01A-01D-1501-10) from TCGA case TCGA-CZ-5463, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 76.4 years (27,911 days).
Specimen TCGA-CZ-5463-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95edc7c0-b823-4c4b-8f7a-9108817e4fc7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CZ-5463-11A (Solid Tissue Normal), aliquot TCGA-CZ-5463-11A-01D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ede1eb3-ab95-4a96-afdb-fa974394e478

The open-access MAF lists 50 somatic variants for this specimen: 37 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 11, Frame Shift Del 3, Frame Shift Ins 2, Nonsense Mutation 2, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 50/118 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADGRL4 | c.1211A>G p.N404S | Missense Mutation (SNP) | VAF 171/461 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.021); catalogued as COSV66061484; called by muse, mutect2, varscan2
- ATG3 | c.555A>C p.K185N | Missense Mutation (SNP) | VAF 239/429 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0.029); catalogued as COSV51926780, COSV99344114; called by muse, varscan2
- B4GALNT3 | c.2573C>A p.S858* | Nonsense Mutation (SNP) | VAF 32/102 reads (31%) | catalogued as COSV56752197; called by muse, mutect2, varscan2
- BCLAF1 | c.353G>T p.R118I | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as rs774404133, COSV62142019, COSV62145966; called by muse, mutect2, varscan2
- CD163L1 | c.3535A>T p.I1179F | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV58015695; called by muse, mutect2, varscan2
- CLCN6 | c.1941G>A p.M647I | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.055); catalogued as COSV56740011; called by muse, mutect2, varscan2
- CLDN10 | c.634G>C p.D212H | Missense Mutation (SNP) | VAF 200/563 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.547); catalogued as COSV54824219; called by muse, mutect2, varscan2
- CR1 | c.5516G>T p.R1839L | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.421); catalogued as COSV65458104; called by muse, mutect2, varscan2
- FYB2 | c.1937T>G p.M646R | Missense Mutation (SNP) | VAF 157/469 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as COSV58584901; called by muse, mutect2, varscan2
- GALNT11 | c.71T>A p.L24H | Missense Mutation (SNP) | VAF 186/512 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV57425818; called by muse, mutect2, varscan2
- GAR1 | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 43/179 reads (24%) | catalogued as COSV56993287; called by muse, mutect2, varscan2
- ITPRID1 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as rs376757677; called by muse, mutect2, varscan2
- KCND2 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58575952; called by muse, mutect2, varscan2
- KCNK5 | c.572T>C p.I191T | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV63988870; called by muse, mutect2, varscan2
- KLHL32 | c.28C>A p.Q10K | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.01); catalogued as COSV65111915; called by muse, mutect2, varscan2
- MARCHF5 | c.822A>T p.E274D | Missense Mutation (SNP) | VAF 113/303 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as COSV62769616; called by muse, mutect2, varscan2
- MMP12 | c.1126T>G p.F376V | Missense Mutation (SNP) | VAF 168/476 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV58259773; called by muse, mutect2
- MMP8 | c.89C>A p.T30K | Missense Mutation (SNP) | VAF 65/210 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.026); catalogued as COSV52632421; called by muse, mutect2, varscan2
- OR2J2 | c.173C>A p.T58K | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV65847791, COSV65848275; called by muse, mutect2, varscan2
- OR4S2 | c.284G>T p.C95F | Missense Mutation (SNP) | VAF 206/553 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56746716; called by muse, mutect2, varscan2
- PPP1R3A | c.3089G>T p.G1030V | Missense Mutation (SNP) | VAF 225/594 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as COSV52881932, COSV52882255; called by muse, mutect2, varscan2
- RABL3 | c.14A>G p.D5G | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV52204183; called by muse, mutect2, varscan2
- RPL26L1 | c.4A>C p.K2Q | Missense Mutation (SNP) | VAF 127/236 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV54199568; called by muse, mutect2, varscan2
- SGIP1 | c.1628A>G p.E543G | Missense Mutation (SNP) | VAF 133/604 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV52768086; called by muse, mutect2, varscan2
- SLCO3A1 | c.1306G>A p.V436I | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.037); catalogued as rs970421099, COSV59229607; called by muse, mutect2, varscan2
- TPRN | c.1610T>A p.L537H | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.873); catalogued as COSV58806400, COSV58807402; called by muse, mutect2, varscan2
- VANGL1 | c.1009G>T p.D337Y | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV100049368, COSV59620425; called by muse, mutect2, varscan2
- VPS13C | c.6850C>G p.Q2284E (on ENST00000644861 / NM_020821.3; = p.Q2241E on NM_017684.5) | Missense Mutation (SNP) | VAF 153/434 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.112); catalogued as COSV51174806; called by muse, mutect2, varscan2
- ZBED8 | c.595_598del p.E199Sfs*2 | Frame Shift Del (DEL) | VAF 73/260 reads (28%) | catalogued as rs775126566; called by mutect2, pindel, varscan2
- ZC3H13 | c.3437C>G p.T1146S | Missense Mutation (SNP) | VAF 161/400 reads (40%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV54453198; called by muse, mutect2, varscan2
- ZMYM2 | c.3991T>C p.C1331R | Missense Mutation (SNP) | VAF 124/404 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0.034); catalogued as COSV67033967; called by muse, mutect2, varscan2
- ZNF677 | c.1457C>A p.P486H | Missense Mutation (SNP) | VAF 101/281 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV61720233, COSV61720649; called by muse, mutect2, varscan2
- GUCY1A1 | c.1179del p.F393Lfs*17 | Frame Shift Del (DEL) | VAF 76/286 reads (27%) | called by mutect2, pindel, varscan2
- MAX | c.102del p.K34Nfs*31 | Frame Shift Del (DEL) | VAF 110/266 reads (41%) | called by mutect2, pindel
- SLC34A1 | c.928dup p.S310Ffs*129 | Frame Shift Ins (INS) | VAF 15/85 reads (18%) | called by mutect2, pindel, varscan2
- SLC3A1 | c.1666dup p.S556Kfs*7 | Frame Shift Ins (INS) | VAF 62/204 reads (30%) | called by mutect2, pindel, varscan2
- AP4M1 | c.315T>C p.N105= | Silent (SNP) | VAF 32/106 reads (30%) | catalogued as rs1471067732, COSV57996293; called by muse, mutect2
- ATP8B3 | c.3306C>T p.R1102= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs752755290, COSV100034918; called by muse, varscan2
- LPCAT3 | c.471T>G p.V157= | Silent (SNP) | VAF 81/250 reads (32%) | catalogued as rs745597690, COSV54645696; called by muse, mutect2, varscan2
- NLRP7 | c.1479C>T p.H493= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as rs763029701, COSV60171565; called by muse, mutect2, varscan2
- OR6S1 | c.843G>A p.T281= | Silent (SNP) | VAF 12/211 reads (6%) | catalogued as rs767095883, COSV57837642; called by muse, mutect2
- POLN | c.1758A>C p.P586= | Silent (SNP) | VAF 26/913 reads (3%) | catalogued as COSV67025190; called by muse, mutect2
- RFC4 | c.846G>A p.Q282= | Silent (SNP) | VAF 32/372 reads (9%) | catalogued as COSV56216870; called by muse, mutect2
- TMEM98 | c.228C>A p.A76= | Silent (SNP) | VAF 78/204 reads (38%) | catalogued as rs1245374181, COSV55582649, COSV55582989; called by muse, mutect2, varscan2
- TPR | c.6909C>A p.T2303= | Silent (SNP) | VAF 58/234 reads (25%) | catalogued as COSV66601264; called by muse, varscan2
- ZFPM2 | c.1014C>T p.T338= | Silent (SNP) | VAF 13/198 reads (7%) | catalogued as rs141238169; called by muse, mutect2
- ZNF609 | c.2046C>A p.G682= | Silent (SNP) | VAF 32/89 reads (36%) | catalogued as COSV58582967; called by muse, mutect2, varscan2
- FAM234B | c.*2C>G | 3'UTR (SNP) | VAF 134/353 reads (38%) | catalogued as COSV99545910; called by muse, mutect2, varscan2
- GAS8 | c.90+1350T>A | Intron (SNP) | VAF 15/31 reads (48%) | catalogued as COSV51943471; called by muse, mutect2, varscan2
